Somatic mutation profile of tumor specimen 0DV991 from CCDI case PBCLWD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0DV991: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a843fa3f-f853-4720-88a1-3441d127bdd4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV98N (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15831195-9c00-42b2-b7bd-2ec23cb4cf15

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, Nonsense Mutation 2, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 177/488 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.615T>G p.Y205* | Nonsense Mutation (SNP) | VAF 227/641 reads (35%) | hotspot (GDC flag); catalogued as COSV52713698, COSV52808763, COSV52840738; called by muse, mutect2, varscan2
- ADAMTS3 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 319/898 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs762763954, COSV54388746; called by muse, mutect2, varscan2
- ATRX | c.5359G>T p.G1787C | Missense Mutation (SNP) | VAF 48/924 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100970213; called by muse, mutect2
- CASP8AP2 | c.2543A>C p.N848T | Missense Mutation (SNP) | VAF 32/866 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52747014; called by muse, mutect2
- CELSR3 | c.4399G>A p.G1467R | Missense Mutation (SNP) | VAF 107/357 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs750148315; called by muse, mutect2, varscan2
- KNDC1 | c.1462G>A p.V488M | Missense Mutation (SNP) | VAF 158/452 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs774623651, COSV58841808; called by muse, mutect2, varscan2
- LCE2D | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 141/502 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.992); catalogued as rs761330190; called by muse, mutect2
- OR4S1 | c.766T>C p.Y256H | Missense Mutation (SNP) | VAF 20/811 reads (2%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1316616821, COSV60678650; called by muse, mutect2
- ASPM | c.2072A>T p.Y691F | Missense Mutation (SNP) | VAF 30/1232 reads (2%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.6); called by muse, mutect2
- ATRX | c.2161C>T p.Q721* | Nonsense Mutation (SNP) | VAF 258/855 reads (30%) | called by muse, mutect2, varscan2
- BAIAP2L2 | c.351C>A p.D117E | Missense Mutation (SNP) | VAF 32/536 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.009); called by muse, mutect2
- C4A | c.2523G>A p.M841I | Missense Mutation (SNP) | VAF 254/1033 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1I | c.5855A>T p.D1952V | Missense Mutation (SNP) | VAF 102/516 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- DGKD | c.2411T>G p.L804R (on ENST00000264057 / NM_152879.3; = p.L760R on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 227/809 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EBF2 | c.871G>T p.V291L | Missense Mutation (SNP) | VAF 38/613 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2
- HUWE1 | c.12098A>G p.E4033G | Missense Mutation (SNP) | VAF 192/688 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- NWD1 | c.3064G>A p.G1022S | Missense Mutation (SNP) | VAF 173/439 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- IGSF9 | c.2493G>A p.P831= (on ENST00000368094 / NM_001135050.2; = p.P815= on NM_020789.4) | Silent (SNP) | VAF 46/210 reads (22%) | catalogued as COSV57422107; called by muse, mutect2, varscan2
- METAP2 | c.1059A>T p.T353= | Silent (SNP) | VAF 141/699 reads (20%) | called by muse, mutect2, varscan2
- RSPH6A | c.1197C>T p.A399= | Silent (SNP) | VAF 78/256 reads (30%) | catalogued as rs770757580; called by muse, mutect2, varscan2
- RTF1 | c.1872C>T p.Y624= | Silent (SNP) | VAF 191/630 reads (30%) | catalogued as rs767661257; called by muse, mutect2, varscan2
- TUBGCP3 | c.1464A>G p.K488= | Silent (SNP) | VAF 30/920 reads (3%) | called by muse, mutect2
- FAM183A | c.*9C>T | 3'UTR (SNP) | VAF 161/400 reads (40%) | catalogued as rs749850046, COSV58923603; called by muse, mutect2, varscan2
- H1-4 | c.-30G>A | 5'UTR (SNP) | VAF 32/560 reads (6%) | catalogued as rs769000080; called by muse, mutect2
